Somatic mutation profile of tumor specimen TCGA-D1-A16E-01A (aliquot TCGA-D1-A16E-01A-22D-A12J-09) from TCGA case TCGA-D1-A16E, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G1; Age at diagnosis: 73.5 years (26,859 days).
Specimen TCGA-D1-A16E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9dd48b99-3afb-48d1-b823-e0e890bc4418.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A16E-10A (Blood Derived Normal), aliquot TCGA-D1-A16E-10A-01D-A12J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ab52c007-ee4c-4156-bf74-3b5326df604c

The open-access MAF lists 69 somatic variants for this specimen: 51 protein-altering or splice-affecting, 18 silent.
By variant classification: Missense Mutation 35, Silent 18, Nonsense Mutation 7, Frame Shift Del 4, Splice Site 2, Frame Shift Ins 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.3826C>T p.R1276* | Nonsense Mutation (SNP) | VAF 78/124 reads (63%) | hotspot (GDC flag); catalogued as COSV61370466; called by muse, mutect2, varscan2
- BCOR | c.4376A>G p.N1459S (on ENST00000378444 / NM_001123385.2; = p.N1425S on NM_017745.6) | Missense Mutation (SNP) | VAF 50/210 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs199538037, COSV60698733; called by muse, mutect2, varscan2
- PIK3CA | c.304_306del p.I102del | In Frame Del (DEL) | VAF 40/128 reads (31%) | hotspot (GDC flag); catalogued as COSV55907633; called by mutect2, pindel, varscan2
- PTEN | c.367C>G p.H123D | Missense Mutation (SNP) | VAF 129/413 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs786204931, CM020755, COSV64290794, COSV64294365; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AFMID | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs926323806, COSV59975724; called by muse, mutect2, varscan2
- ATP6V1H | c.768G>C p.M256I | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV62217759; called by muse, mutect2, varscan2
- BRAT1 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369391505; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCKAR | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 70/318 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs781540707, COSV55160930; called by muse, mutect2, varscan2
- CDON | c.2032dup p.T678Nfs*18 | Frame Shift Ins (INS) | VAF 127/521 reads (24%) | catalogued as rs768236792; called by mutect2, pindel, varscan2
- CHD4 | c.4298G>A p.R1433K (on ENST00000357008 / NM_001363606.2; = p.R1446K on NM_001273.5) | Missense Mutation (SNP) | VAF 43/159 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as rs770630218, COSV58898433; called by muse, mutect2, varscan2
- CR2 | c.2860C>A p.Q954K | Missense Mutation (SNP) | VAF 72/273 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.542); catalogued as COSV65507054; called by muse, mutect2, varscan2
- CTSZ | c.202T>A p.W68R | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53882940; called by muse, mutect2, varscan2
- CYP2A13 | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 43/168 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.184); catalogued as rs747386782, COSV57836220; called by muse, mutect2, varscan2
- DENND2B | c.2131C>T p.R711* | Nonsense Mutation (SNP) | VAF 57/207 reads (28%) | catalogued as COSV58202703; called by muse, mutect2, varscan2
- ESRP1 | c.702G>A p.W234* | Nonsense Mutation (SNP) | VAF 184/326 reads (56%) | catalogued as COSV64408855; called by muse, mutect2, varscan2
- GRM4 | c.1798G>A p.A600T | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.138); catalogued as rs1473342035, COSV65212266; called by muse, mutect2, varscan2
- GUCY2F | c.883T>C p.Y295H | Missense Mutation (SNP) | VAF 110/355 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as COSV54300591; called by muse, mutect2
- HNF4G | c.818A>G p.Y273C (on ENST00000354370 / NM_001330561.2; = p.Y320C on NM_004133.5) | Missense Mutation (SNP) | VAF 99/184 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100584770, COSV62967083; called by muse, mutect2, varscan2
- IFNA13 | c.157T>A p.C53S | Missense Mutation (SNP) | VAF 28/194 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV71924474; called by muse, mutect2, varscan2
- IGHM | c.1180G>A p.A394T | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.691); catalogued as rs782119828; called by muse, mutect2, varscan2
- INTS1 | c.4003G>C p.G1335R | Missense Mutation (SNP) | VAF 55/178 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0.11); catalogued as COSV67177067; called by muse, mutect2, varscan2
- KBTBD2 | c.361C>T p.R121* | Nonsense Mutation (SNP) | VAF 12/42 reads (29%) | catalogued as rs1168828875, COSV58363230; called by muse, mutect2
- KIF2B | c.1626dup p.L543Ifs*18 | Frame Shift Ins (INS) | VAF 30/111 reads (27%) | catalogued as rs745728329; called by mutect2, varscan2
- LMAN2L | c.668C>T p.T223M | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375965191; called by muse, mutect2, varscan2
- MBD5 | c.1231A>G p.T411A | Missense Mutation (SNP) | VAF 52/183 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as COSV68696463; called by muse, mutect2, varscan2
- MKI67 | c.8450del p.D2817Vfs*15 | Frame Shift Del (DEL) | VAF 170/648 reads (26%) | catalogued as COSV64073752; called by mutect2, pindel, varscan2
- MPP2 | c.1102C>T p.R368C (on ENST00000461854 / NM_001278372.2; = p.R344C on NM_005374.5) | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1374159780, COSV52234924; called by muse, mutect2, varscan2
- MPRIP | c.1313G>A p.C438Y | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs1291114577, COSV59046882; called by muse, mutect2, varscan2
- NFE2L2 | c.127C>G p.R43G | Missense Mutation (SNP) | VAF 92/311 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as COSV67960823; called by muse, mutect2, varscan2
- PDILT | c.227G>A p.R76K | Missense Mutation (SNP) | VAF 117/440 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.03); catalogued as COSV56700972; called by muse, mutect2, varscan2
- PGK1 | c.965A>C p.K322T | Missense Mutation (SNP) | VAF 109/394 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV59371105, COSV59372511; called by muse, mutect2, varscan2
- PHF2 | c.2080A>T p.R694W | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63680104; called by muse, mutect2, varscan2
- PIAS1 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 67/246 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as COSV51031148; called by muse, mutect2, varscan2
- POLR3B | c.2219C>G p.T740R | Missense Mutation (SNP) | VAF 61/234 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV57277819; called by muse, mutect2, varscan2
- PPFIA2 | c.2626C>T p.R876* | Nonsense Mutation (SNP) | VAF 64/290 reads (22%) | catalogued as COSV61027580; called by muse, mutect2, varscan2
- PRKCE | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.014); catalogued as COSV60316254; called by muse, mutect2, varscan2
- PSD2 | c.1205C>T p.S402L | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as rs1311237986, COSV51198480; called by muse, mutect2, varscan2
- PTH | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 100/261 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.053); catalogued as COSV56378353; called by muse, mutect2, varscan2
- RBM26 | c.2620C>T p.R874* (on ENST00000438737 / NM_001366735.2; = p.R847* on NM_022118.5) | Nonsense Mutation (SNP) | VAF 78/233 reads (33%) | catalogued as COSV57393243; called by muse, mutect2, varscan2
- RCOR3 | c.1162C>T p.P388S | Missense Mutation (SNP) | VAF 128/466 reads (27%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs772467312, COSV65365421; called by muse, mutect2, varscan2
- RFESD | c.175+1G>A p.X59_splice | Splice Site (SNP) | VAF 71/256 reads (28%) | catalogued as rs148197241; called by muse, mutect2, varscan2
- SEMA3C | c.1111C>T p.P371S | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54844444, COSV54856079; called by muse, mutect2, varscan2
- SIPA1L2 | c.2330G>A p.R777Q | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372124843; called by muse, mutect2, varscan2
- TIAM1 | c.4027C>T p.R1343* | Nonsense Mutation (SNP) | VAF 30/104 reads (29%) | catalogued as COSV54545064; called by muse, mutect2, varscan2
- TMEM143 | c.589G>A p.V197I | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1352287384, COSV53155983; called by muse, mutect2, varscan2
- UNC5A | c.2020-2A>G p.X674_splice | Splice Site (SNP) | VAF 21/86 reads (24%) | catalogued as COSV52838679; called by muse, mutect2, varscan2
- WDFY3 | c.6614C>T p.T2205I | Missense Mutation (SNP) | VAF 67/228 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV55697723; called by muse, mutect2, varscan2
- XK | c.1154C>T p.S385F | Missense Mutation (SNP) | VAF 58/218 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.101); catalogued as COSV66119980; called by muse, mutect2, varscan2
- ECT2L | c.2395_2398del p.E799* | Frame Shift Del (DEL) | VAF 45/162 reads (28%) | called by mutect2, pindel, varscan2
- FUT11 | c.747_750del p.T251Rfs*38 | Frame Shift Del (DEL) | VAF 18/61 reads (30%) | called by mutect2, pindel, varscan2
- PTEN | c.208_209del p.A72* | Frame Shift Del (DEL) | VAF 32/139 reads (23%) | called by mutect2, pindel, varscan2
- CASR | c.648C>T p.D216= | Silent (SNP) | VAF 57/235 reads (24%) | catalogued as rs774470582, COSV56134230; ClinVar: likely benign; called by muse, mutect2, varscan2
- DHX40 | c.2020T>C p.L674= | Silent (SNP) | VAF 52/290 reads (18%) | catalogued as COSV52066905; called by muse, mutect2, varscan2
- ELOVL2 | c.555C>T p.S185= | Silent (SNP) | VAF 49/168 reads (29%) | catalogued as COSV61154751; called by muse, mutect2, varscan2
- EVX2 | c.843C>T p.H281= | Silent (SNP) | VAF 12/52 reads (23%) | called by muse, mutect2
- FOXA3 | c.792C>T p.G264= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as rs539294853, COSV56215416; called by muse, mutect2, varscan2
- IGF2 | c.45C>T p.T15= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as COSV56098042; called by muse, mutect2, varscan2
- IRX6 | c.1281C>T p.C427= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV51859962; called by muse, mutect2, varscan2
- LAMP2 | c.675T>G p.V225= | Silent (SNP) | VAF 120/483 reads (25%) | catalogued as rs745437545, COSV52352391, COSV99568755; called by muse, varscan2
- NOL4 | c.1752A>G p.Q584= | Silent (SNP) | VAF 89/292 reads (30%) | catalogued as rs1191533888, COSV52343873; called by muse, mutect2, varscan2
- PZP | c.1299A>T p.V433= | Silent (SNP) | VAF 45/152 reads (30%) | catalogued as COSV54357834; called by muse, mutect2, varscan2
- SOX30 | c.867C>T p.V289= | Silent (SNP) | VAF 49/151 reads (32%) | catalogued as COSV53936848; called by muse, mutect2, varscan2
- SPSB3 | c.162G>A p.T54= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as rs762523870, COSV51905349; called by muse, mutect2, varscan2
- SRRM2 | c.585T>C p.D195= | Silent (SNP) | VAF 62/217 reads (29%) | catalogued as COSV57071385; called by muse, mutect2, varscan2
- SYNE3 | c.1308C>T p.A436= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs1303666861, COSV62078895; called by muse, mutect2, varscan2
- TAF6 | c.744G>T p.T248= | Silent (SNP) | VAF 51/134 reads (38%) | catalogued as rs750627253, COSV59841230; called by muse, mutect2, varscan2
- TESK2 | c.1608G>A p.A536= | Silent (SNP) | VAF 48/176 reads (27%) | catalogued as rs200676018, COSV59150894; called by muse, mutect2, varscan2
- WSCD1 | c.1527C>T p.N509= | Silent (SNP) | VAF 26/90 reads (29%) | catalogued as rs560772475, COSV58494864; called by muse, mutect2, varscan2
- ZFYVE1 | c.1977C>T p.N659= | Silent (SNP) | VAF 34/115 reads (30%) | catalogued as rs759101141, COSV59609802; called by muse, mutect2, varscan2
